Surgical pathology report (de-identified scan), TCGA case TCGA-C4-A0F1, project TCGA-BLCA (Bladder Urothelial Carcinoma), tissue source site Indivumed, specimen TCGA-C4-A0F1-01A (Primary Tumor).

ICD-0-3

Carcinoma, urothelial, NOS 8/20/3

Site: bladder, NOS C67.9

1/28/11 *lw*

Diagnosis

1. Cystoprostatectomy preparation with a moderately differentiated, solid urothelial carcinoma of squamous epithelial differentiation mainly in the right trigone, with penetration of all parietal layers and macroscopic infiltration of the perivesical fatty tissue. Three tumor-free lymph nodes. Deep resection margins, including urethra, ureters and vas deferens, are tumor-free (compare frozen section, admission no. ---). Foci of moderate dysplasia of the remaining bladder urothelium.

Comment:

Tumor classification of the bladder carcinoma: pT3b, pN0 (0/9), L0, V0, R0, G2; maximum tumor size 2.5 cm.

Source: NCI Genomic Data Commons file 5736472e-1133-4996-8e59-8328378b0114 (TCGA-C4-A0F1.8410F811-09E4-40B9-B3CF-5A6F3DE628BD.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).